Somatic mutation profile of cancer-model specimen HCM-BROD-0200-C71-85B (Adherent Cell Line, passage 10; aliquot HCM-BROD-0200-C71-85B-01D-A78T-36), derived from the primary tumor of HCMI case HCM-BROD-0200-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.2 years (27,463 days).
Specimen HCM-BROD-0200-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12a6f4a4-4b22-4fde-bab1-825990919d98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0200-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0200-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62f328d4-d536-48ab-97d2-a8bbda7d573e

The open-access MAF lists 123 somatic variants for this specimen: 83 protein-altering or splice-affecting, 25 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 25, Intron 8, Nonsense Mutation 4, Splice Site 4, 5'UTR 3, 3'UTR 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRA1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 133/326 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs727503940, COSV50119921, COSV99195708; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ALPG | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 144/330 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs770957226, COSV54966433; called by muse, mutect2, varscan2
- ANKFY1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 81/149 reads (54%) | catalogued as rs779067805; called by muse, mutect2, varscan2
- ARFGEF3 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1326151522, COSV52472440; called by muse, mutect2, varscan2
- ARHGAP24 | c.180+1G>C p.X60_splice | Splice Site (SNP) | VAF 9/132 reads (7%) | catalogued as COSV101232969; called by muse, mutect2
- ARHGEF15 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1480801589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATL1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 98/335 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs976793999, COSV63296138; called by muse, mutect2, varscan2
- ATP4A | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 131/271 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as rs144661332; called by muse, mutect2, varscan2
- CACNA1S | c.3808G>A p.V1270M | Missense Mutation (SNP) | VAF 231/386 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749105028; called by muse, mutect2, varscan2
- CIT | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 84/165 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs749312866; called by muse, mutect2, varscan2
- COL11A1 | c.4793G>A p.G1598D | Missense Mutation (SNP) | VAF 135/266 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100614254; called by muse, mutect2, varscan2
- CUL3 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs760276064, COSV52369144; called by muse, mutect2, varscan2
- ELFN2 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs376827195; called by muse, mutect2, varscan2
- GCGR | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 161/349 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.903); catalogued as rs947813160; called by muse, mutect2, varscan2
- GDF10 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 103/103 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs781814156; called by muse, mutect2, varscan2
- GRM5 | c.2893G>A p.A965T (on ENST00000305447 / NM_001143831.2; = p.A933T on NM_000842.4) | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV59604206; called by muse, mutect2, varscan2
- HTR3A | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs540212344, COSV55468983; called by muse, mutect2, varscan2
- KCNS2 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs781697576, COSV54637693; called by muse, mutect2, varscan2
- KLHL7 | c.881G>A p.R294H (on ENST00000339077 / NM_001031710.3; = p.R246H on NM_018846.5) | Missense Mutation (SNP) | VAF 225/865 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1043587892, COSV59165446; called by muse, mutect2, varscan2
- KPRP | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs1445616839, COSV64221535; called by muse, mutect2, varscan2
- LAMA2 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 77/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs981472642; called by muse, mutect2, varscan2
- LCE1F | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 178/403 reads (44%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.026); catalogued as rs553837591, COSV57668776; called by muse, mutect2, varscan2
- LMO2 | c.255C>T p.L85= (on ENST00000395833 / NM_001142315.2; = p.L154= on NM_005574.4) | Splice Region (SNP) | VAF 15/90 reads (17%) | catalogued as COSV99137898; called by muse, mutect2, varscan2
- MGAM | c.4417G>A p.G1473S | Missense Mutation (SNP) | VAF 199/943 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as rs758607719; called by muse, mutect2, varscan2
- NDRG1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 119/258 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs777244818; called by muse, mutect2, varscan2
- NEUROD6 | c.966C>A p.S322R | Missense Mutation (SNP) | VAF 102/384 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV51772590; called by muse, mutect2, varscan2
- OR51B2 | c.254T>A p.V85E | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as rs1187232538; called by muse, mutect2, varscan2
- OR7G2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as rs1220167316; called by muse, mutect2
- P2RY8 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 154/338 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.825); catalogued as rs1382755800; called by muse, mutect2, varscan2
- PAN2 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 229/562 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99228196; called by muse, mutect2, varscan2
- PCLO | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV61654498; called by muse, mutect2, varscan2
- PIBF1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 86/86 reads (100%) | catalogued as rs374837848; called by muse, mutect2, varscan2
- PKHD1 | c.6818C>T p.T2273M | Missense Mutation (SNP) | VAF 138/320 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs375784210; called by muse, mutect2, varscan2
- PLXNA4 | c.4484T>C p.I1495T | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1314184431; called by muse, mutect2
- PPP1R3E | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1213719289; called by muse, mutect2, varscan2
- PTEN | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 197/203 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1564830084, COSV64294745, COSV64299772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTP4A2 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs1011744907; called by muse, mutect2, varscan2
- RBM11 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs528749430; called by muse, mutect2, varscan2
- SCN9A | c.596+1G>A p.X199_splice | Splice Site (SNP) | VAF 66/167 reads (40%) | catalogued as rs201560701, COSV57606863, COSV57616568; called by muse, mutect2, varscan2
- SCUBE1 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs772360095, COSV100683408; called by muse, mutect2, varscan2
- SYNDIG1 | c.407T>A p.L136H | Missense Mutation (SNP) | VAF 86/343 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV65234737; called by muse, mutect2, varscan2
- TAS2R1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs767333394; called by muse, mutect2, varscan2
- TEX2 | c.3329G>A p.R1110H (on ENST00000583097 / NM_001288733.2; = p.R1117H on NM_018469.5) | Missense Mutation (SNP) | VAF 94/226 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs778477556, COSV51979048, COSV51982534; called by muse, mutect2, varscan2
- TLR5 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 157/402 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100643420; called by muse, mutect2, varscan2
- TRDN | c.1128G>T p.K376N | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV62121110, COSV62133905; called by muse, mutect2, varscan2
- TRIM29 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 171/403 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV100531800; called by muse, mutect2, varscan2
- TRIM66 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1313317277; called by muse, mutect2, varscan2
- TTN | c.29161G>T p.V9721L (on ENST00000591111; = p.V8794L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/362 reads (6%) | PolyPhen benign (0.419); catalogued as COSV59983264; called by muse, mutect2
- USP37 | c.2753C>T p.A918V | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.063); catalogued as rs780874508, COSV50285389; called by muse, mutect2, varscan2
- XDH | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 162/427 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs780502467; called by muse, mutect2, varscan2
- ZFR2 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 96/245 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs558302396; called by muse, mutect2, varscan2
- ZNF578 | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 147/319 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs777923491; called by muse, mutect2, varscan2
- BNC2 | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- C16orf54 | c.539T>A p.V180D | Missense Mutation (SNP) | VAF 43/363 reads (12%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CDH11 | c.1078A>G p.S360G | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CNTNAP4 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- DPF2 | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 76/138 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FBN2 | c.5801-1G>C p.X1934_splice | Splice Site (SNP) | VAF 63/284 reads (22%) | called by muse, mutect2, varscan2
- FSIP2 | c.7567T>A p.S2523T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- GHRHR | c.105A>T p.R35S | Missense Mutation (SNP) | VAF 78/1036 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.055); called by muse, mutect2
- GRM3 | c.1719A>T p.E573D | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- HEMGN | c.1403T>C p.I468T | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HOXB9 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KDM7A | c.358A>G p.R120G | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.051); called by muse, mutect2
- MGAT3 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- MS4A15 | c.498+1G>T p.X166_splice (on ENST00000405633 / NM_001098835.2; = p.X73_splice on NM_152717.3) | Splice Site (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- MSH4 | c.1292T>C p.V431A | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- OR2F2 | c.806T>A p.L269H | Missense Mutation (SNP) | VAF 99/389 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR4K1 | c.760T>A p.C254S | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- OTOG | c.3313C>A p.P1105T | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH11Y | c.403G>A p.D135N (on ENST00000400457 / NM_032973.2; = p.D124N on NM_032971.3) | Missense Mutation (SNP) | VAF 136/292 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- PKHD1 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 143/294 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RHAG | c.983G>T p.C328F | Missense Mutation (SNP) | VAF 57/520 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SF3B3 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC38A8 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 141/358 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC9A5 | c.2587C>G p.Q863E | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.585); called by mutect2, varscan2
- SPATA31A3 | c.2179G>C p.E727Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by mutect2, varscan2
- SPTBN1 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- THSD4 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- TMEFF2 | c.965T>A p.I322N | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPK1 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- VPS8 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 104/200 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZBBX | c.2141C>A p.T714N | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADAP1 | c.177C>T p.S59= | Silent (SNP) | VAF 122/492 reads (25%) | catalogued as rs1397009559; called by muse, mutect2, varscan2
- APLP1 | c.1620G>A p.K540= (on ENST00000221891 / NM_001024807.3; = p.K539= on NM_005166.4) | Silent (SNP) | VAF 154/347 reads (44%) | catalogued as rs1431497657; called by muse, mutect2, varscan2
- ATP10B | c.1044C>T p.F348= | Silent (SNP) | VAF 54/120 reads (45%) | catalogued as rs541851085, COSV58781352; called by muse, mutect2, varscan2
- CCDC198 | c.867C>T p.F289= | Silent (SNP) | VAF 113/213 reads (53%) | catalogued as rs146789384; called by muse, mutect2, varscan2
- CLRN1 | c.168G>A p.K56= | Silent (SNP) | VAF 21/257 reads (8%) | called by muse, mutect2
- EMP2 | c.456C>T p.C152= | Silent (SNP) | VAF 52/105 reads (50%) | called by muse, mutect2, varscan2
- FLNB | c.852C>T p.A284= | Silent (SNP) | VAF 23/331 reads (7%) | catalogued as rs765017696; ClinVar: uncertain significance; called by muse, mutect2
- FN1 | c.1428C>T p.V476= | Silent (SNP) | VAF 57/453 reads (13%) | called by muse, mutect2, varscan2
- FNDC1 | c.2403G>A p.A801= | Silent (SNP) | VAF 136/255 reads (53%) | catalogued as COSV51930088; called by muse, mutect2, varscan2
- HECW1 | c.1650C>T p.C550= | Silent (SNP) | VAF 132/488 reads (27%) | catalogued as rs763924846, COSV67833539; called by muse, mutect2, varscan2
- HRH2 | c.546C>T p.Y182= | Silent (SNP) | VAF 129/268 reads (48%) | catalogued as rs772344735; called by muse, mutect2, varscan2
- IL24 | c.297C>T p.N99= | Silent (SNP) | VAF 129/261 reads (49%) | catalogued as rs761273178, COSV54321632; called by muse, mutect2, varscan2
- LARS1 | c.1032C>T p.G344= (on ENST00000394434 / NM_020117.11; = p.G317= on NM_016460.3) | Silent (SNP) | VAF 137/266 reads (52%) | catalogued as rs749791589, COSV50974416; called by muse, mutect2, varscan2
- RCN3 | c.525C>T p.A175= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as rs775089420, COSV54543337; called by muse, mutect2, varscan2
- SLC2A14 | c.75G>C p.P25= | Silent (SNP) | VAF 78/78 reads (100%) | catalogued as rs777834662; called by muse, mutect2, varscan2
- SPANXN2 | c.183G>A p.T61= | Silent (SNP) | VAF 192/192 reads (100%) | catalogued as rs782774590, COSV65127684; called by muse, varscan2
- SPTA1 | c.1674C>T p.D558= | Silent (SNP) | VAF 159/390 reads (41%) | catalogued as rs780161347, COSV63750189; called by muse, mutect2, varscan2
- SSTR5 | c.306G>A p.A102= | Silent (SNP) | VAF 164/415 reads (40%) | catalogued as rs1354513472; called by muse, mutect2, varscan2
- TFAP2C | c.45C>T p.C15= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- TPBG | c.93G>A p.S31= | Silent (SNP) | VAF 83/175 reads (47%) | called by muse, mutect2, varscan2
- TPSD1 | c.174C>T p.R58= | Silent (SNP) | VAF 59/207 reads (29%) | catalogued as rs778229260, COSV52974243; called by muse, mutect2, varscan2
- TRAV25 | c.117G>A p.T39= | Silent (SNP) | VAF 72/134 reads (54%) | called by muse, mutect2, varscan2
- TSSK6 | c.759C>T p.S253= | Silent (SNP) | VAF 145/292 reads (50%) | catalogued as rs760900701; called by muse, mutect2, varscan2
- UCKL1 | c.57G>A p.T19= | Silent (SNP) | VAF 93/192 reads (48%) | catalogued as rs535689162; called by muse, mutect2, varscan2
- UGT2B17 | c.1362G>A p.P454= | Silent (SNP) | VAF 85/193 reads (44%) | catalogued as rs746870450; called by muse, mutect2, varscan2
- CCDC40 | c.1562+1913G>A | Intron (SNP) | VAF 79/146 reads (54%) | catalogued as rs1190336053; called by muse, mutect2, varscan2
- CGB7 | c.-10C>T | 5'UTR (SNP) | VAF 62/369 reads (17%) | catalogued as rs751655312, COSV100655131; called by muse, mutect2, varscan2
- COL1A2 | c.2404-14A>T | Intron (SNP) | VAF 36/518 reads (7%) | called by muse, mutect2
- EPOR | c.*497C>T | 3'UTR (SNP) | VAF 240/510 reads (47%) | called by muse, mutect2, varscan2
- EYS | c.-23C>A | 5'UTR (SNP) | VAF 59/135 reads (44%) | catalogued as COSV100675539; called by muse, mutect2, varscan2
- GRAMD1A | c.-25G>A | 5'UTR (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- KARS1 | c.62+45C>A | Intron (SNP) | VAF 199/332 reads (60%) | called by muse, mutect2, varscan2
- KLF6 | c.*1836T>C | 3'UTR (SNP) | VAF 68/68 reads (100%) | called by muse, mutect2, varscan2
- KRT17P2 | n.311G>A | RNA (SNP) | VAF 101/394 reads (26%) | catalogued as rs1432370230; called by muse, mutect2, varscan2
- MICALL2 | c.641+47C>A | Intron (SNP) | VAF 174/743 reads (23%) | called by muse, varscan2
- PDLIM5 | c.921-6871C>A | Intron (SNP) | VAF 61/252 reads (24%) | called by muse, mutect2, varscan2
- TPM1 | c.563+15C>T | Intron (SNP) | VAF 101/217 reads (47%) | catalogued as rs368177044; called by muse, mutect2, varscan2
- TTC7B | c.699-3626A>G | Intron (SNP) | VAF 106/229 reads (46%) | called by muse, mutect2, varscan2
- UBBP4 | n.454del | RNA (DEL) | VAF 34/194 reads (18%) | called by mutect2, pindel
- ZAP70 | c.1082+34C>T | Intron (SNP) | VAF 58/158 reads (37%) | catalogued as rs1256273879; called by muse, mutect2, varscan2
